Somatic mutation profile of tumor specimen TCGA-49-4507-01A (aliquot TCGA-49-4507-01A-01D-1265-08) from TCGA case TCGA-49-4507, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Main bronchus; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.5 years (26,851 days).
Specimen TCGA-49-4507-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 074862f2-acbf-4141-a72a-da28c9cb5f39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4507-11A (Solid Tissue Normal), aliquot TCGA-49-4507-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3015eea2-632f-4290-99eb-76e8d88a14f2

The open-access MAF lists 211 somatic variants for this specimen: 163 protein-altering or splice-affecting, 44 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 44, Nonsense Mutation 10, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 2, Splice Site 2, RNA 1, Intron 1, 3'UTR 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.6871C>T p.Q2291* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as rs1561610839, COSV57347390; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV50260643, COSV50262012; called by muse, mutect2, varscan2
- ABRA | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs766114154, COSV61731909; called by muse, mutect2, varscan2
- AC100868.1 | c.1925A>G p.H642R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.012); catalogued as COSV99226035; called by muse, mutect2, varscan2
- ACAD9 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as rs1266273831, COSV58306959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AK5 | c.106G>T p.E36* (on ENST00000354567 / NM_174858.3; = p.E10* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV58356127; called by muse, mutect2, varscan2
- AKR1B1 | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as COSV53647670; called by muse, mutect2, varscan2
- ALPP | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); catalogued as COSV67396713; called by muse, mutect2, varscan2
- ANK3 | c.7348G>A p.D2450N | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV55063381; called by muse, mutect2, varscan2
- ANKRD30A | c.678G>T p.Q226H (on ENST00000611781; = p.Q170H on NM_052997.2) | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV64612865; called by muse, varscan2
- ANKRD30A | c.1007C>G p.S336C (on ENST00000611781; = p.S280C on NM_052997.2) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs560930371, COSV64612872; called by muse, mutect2, varscan2
- ANKS1B | c.2123G>C p.G708A | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61350254, COSV61357244; called by muse, mutect2, varscan2
- ANXA11 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as COSV99627127; called by muse, mutect2, varscan2
- ARHGAP35 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV68332507; called by muse, mutect2, varscan2
- ARL15 | c.287A>T p.Y96F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV72290914; called by muse, mutect2, varscan2
- ATM | c.8158G>C p.D2720H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs876659942, CM160106, COSV53748743, COSV53750700, COSV53766226; ClinVar: uncertain significance; called by mutect2, varscan2
- ATRN | c.1104G>T p.M368I | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV53529166; called by muse, mutect2, varscan2
- B3GNT3 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV100427576, COSV100427647, COSV57952797; called by muse, mutect2, varscan2
- BLOC1S2 | c.422A>T p.K141M | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV100951795; called by muse, mutect2, varscan2
- BLZF1 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61393933; called by muse, mutect2, varscan2
- BOC | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.857); catalogued as COSV56352836, COSV56358675; called by muse, mutect2, varscan2
- CABCOCO1 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57592395, COSV57593597; called by muse, mutect2
- CASP8 | c.1013C>G p.S338C (on ENST00000432109 / NM_033355.3; = p.S355C on NM_001228.4) | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV51852824, COSV51861829; called by muse, mutect2, varscan2
- CCDC136 | c.2893C>G p.R965G | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52800762; called by muse, mutect2, varscan2
- CCDC82 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV53593922, COSV99567611; called by muse, mutect2
- CCT5 | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV54724380; called by mutect2, varscan2
- CCT5 | c.451A>T p.I151F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99725320; called by mutect2, varscan2
- CCT5 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as COSV54724409; called by muse, mutect2, varscan2
- CD93 | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV55666032; called by muse, mutect2
- CDC123 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV55398108; called by muse, mutect2, varscan2
- CDC5L | c.572T>G p.L191R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65176393; called by muse, varscan2
- CDH12 | c.2230A>T p.S744C | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as COSV66414078; called by muse, mutect2, varscan2
- CDH23 | c.1489T>C p.Y497H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV54938950; called by muse, mutect2, varscan2
- CENPE | c.6146A>G p.E2049G | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV54382900; called by muse, mutect2, varscan2
- CHID1 | c.118T>A p.F40I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100059345, COSV60259406; called by muse, mutect2, varscan2
- CLCA3P | n.464G>A | Splice Region (SNP) | VAF 50/138 reads (36%) | catalogued as rs373518265; called by muse, mutect2, varscan2
- CLIP2 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56274053, COSV56280691; called by muse, mutect2
- CMKLR1 | c.647G>T p.R216L (on ENST00000312143 / NM_001142344.2; = p.R214L on NM_004072.3) | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV100379114, COSV56439069; called by muse, mutect2, varscan2
- CNTNAP2 | c.3179C>A p.A1060E | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as CM161903, COSV62198401; called by muse, mutect2, varscan2
- CPED1 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV60004731; called by muse, mutect2
- CUL5 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV67609227; called by muse, mutect2, varscan2
- DCAF8L1 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV71595353; called by muse, mutect2, varscan2
- DCTN1 | c.3462G>T p.Q1154H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV100720944; called by muse, mutect2, varscan2
- DCTN1 | c.3461A>T p.Q1154L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV100720945; called by muse, mutect2, varscan2
- DDX27 | c.1768A>G p.I590V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as COSV65608453; called by muse, mutect2, varscan2
- DIO3 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV63773873; called by muse, mutect2
- DLG3 | c.2326G>A p.E776K (on ENST00000374360 / NM_021120.4; = p.E471K on NM_020730.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV52083604; called by muse, mutect2, varscan2
- DLG5 | c.2939A>C p.K980T | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV64948465; called by muse, mutect2, varscan2
- DNAH17 | c.5246A>G p.D1749G | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67756761; called by muse, mutect2, varscan2
- DST | c.11527C>T p.Q3843* (on ENST00000361203 / NM_001374722.1; = p.Q1431* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 18/122 reads (15%) | catalogued as COSV55021262; called by muse, mutect2, varscan2
- ETAA1 | c.2312C>G p.P771R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV55473544; called by muse, mutect2
- EXOC4 | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV54103366; called by muse, mutect2, varscan2
- FAM76A | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV50549197; called by muse, mutect2, varscan2
- FAM8A1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1366000323, COSV52580283, COSV52580559; called by muse, varscan2
- FUS | c.1542-1G>T p.X514_splice | Splice Site (SNP) | VAF 22/105 reads (21%) | catalogued as COSV54217841; called by muse, mutect2, varscan2
- GRPR | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV66669666; called by muse, mutect2, varscan2
- HSPA1L | c.1806G>C p.E602D | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV65150690; called by muse, mutect2, varscan2
- IGBP1 | c.622A>T p.I208F | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100642965; called by muse, mutect2, varscan2
- ITGA7 | c.248A>T p.Q83L | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV57696474; called by muse, mutect2, varscan2
- ITGA8 | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV65230373; called by muse, mutect2, varscan2
- KCNH8 | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.173); catalogued as COSV60466941; called by muse, mutect2, varscan2
- KCNJ3 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV54538132; called by muse, mutect2, varscan2
- KCTD7 | c.773C>T p.S258L (on ENST00000275532; = p.L271= on NM_153033.5) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as rs766332054, COSV51878037; called by muse, mutect2, varscan2
- KERA | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899427, COSV99899567; called by muse, mutect2, varscan2
- KIF19 | c.2690A>T p.E897V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63429693; called by muse, mutect2
- KLHDC7A | c.1837G>C p.D613H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101272770; called by muse, mutect2, varscan2
- KLRD1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV60273928; called by muse, mutect2, varscan2
- KRT2 | c.534G>C p.E178D | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296315162, COSV59010978; called by muse, mutect2, varscan2
- KRT6B | c.1175G>T p.R392I | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52884334; called by muse, mutect2, varscan2
- KRTAP19-3 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV100477532; called by muse, mutect2, varscan2
- LENG8 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as COSV58728463; called by muse, mutect2, varscan2
- LIPG | c.237C>G p.F79L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV54296728; called by muse, mutect2
- LNPEP | c.1390C>T p.H464Y | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165225079, COSV51478649; called by muse, mutect2, varscan2
- LRCH1 | c.1427G>T p.S476I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV60848735; called by muse, varscan2
- LRRC4C | c.1225G>T p.G409C | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53428721; called by muse, varscan2
- LUZP1 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 34/192 reads (18%) | catalogued as COSV56500113; called by muse, mutect2, varscan2
- MCTS1 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV64892570; called by muse, mutect2, varscan2
- MMS22L | c.1397G>T p.C466F | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV51522202; called by muse, mutect2, varscan2
- MUC16 | c.16243G>A p.A5415T | Missense Mutation (SNP) | VAF 195/616 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs758745630, COSV67473688; called by muse, mutect2, varscan2
- MUC7 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 30/169 reads (18%) | catalogued as COSV59218770; called by muse, mutect2, varscan2
- MYADM | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100425050; called by muse, mutect2, varscan2
- NEUROD6 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV99774038; called by muse, mutect2, varscan2
- NFATC2 | c.1889A>G p.K630R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.363); catalogued as rs1036824890, COSV101044066; called by muse, mutect2
- NLRP10 | c.1655T>A p.M552K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV60780761; called by muse, mutect2, varscan2
- NOL4 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.266); catalogued as COSV52347422, COSV52350395; called by muse, mutect2, varscan2
- NPC1L1 | c.3889A>T p.N1297Y | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56926322; called by muse, mutect2, varscan2
- NPNT | c.778A>C p.M260L | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV59754685; called by muse, mutect2, varscan2
- NTM | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV66264523; called by muse, mutect2, varscan2
- NUBP2 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51906436; called by muse, mutect2, varscan2
- OR10K2 | c.920G>T p.R307I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV59221562; called by muse, mutect2, varscan2
- OR10T2 | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57781811; called by mutect2, varscan2
- OR5W2 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs754041941, COSV60616626; called by muse, mutect2, varscan2
- OR8H2 | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); catalogued as COSV57945388, COSV57947179; called by muse, mutect2
- OR8K5 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV57888808, COSV57889280, COSV57889510; called by muse, mutect2
- PCDHB13 | c.2083G>T p.A695S | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as COSV53397703; called by muse, mutect2, varscan2
- PCDHGA11 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1243671863, COSV53967557, COSV54024998; called by muse, mutect2, varscan2
- PCLO | c.15397A>T p.K5133* | Nonsense Mutation (SNP) | VAF 25/191 reads (13%) | catalogued as COSV100425884, COSV61642054; called by muse, mutect2, varscan2
- PCNP | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.918); catalogued as COSV54576493; called by muse, mutect2, varscan2
- PCSK5 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1304966454, COSV65090710; called by muse, mutect2, varscan2
- PCSK5 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65084007; called by muse, mutect2, varscan2
- PCSK5 | c.1259G>T p.R420L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs778416029, COSV65090732; called by muse, mutect2, varscan2
- PIKFYVE | c.5359G>A p.G1787S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV52243170; called by muse, mutect2, varscan2
- PKHD1L1 | c.6169A>G p.N2057D | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV65745489; called by muse, mutect2
- PLA2G3 | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as COSV53210332; called by muse, mutect2, varscan2
- PLEC | c.11432G>A p.R3811H (on ENST00000322810 / NM_201380.4; = p.R3701H on NM_000445.5) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs782720846, COSV59649582; ClinVar: uncertain significance; called by muse, mutect2
- POLR1F | c.813G>T p.W271C | Missense Mutation (SNP) | VAF 163/703 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55998804; called by muse, mutect2, varscan2
- PRKD2 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1326449512, COSV52187554; called by muse, mutect2, varscan2
- PRMT8 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 195/549 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs762604837, COSV54215313; called by muse, mutect2, varscan2
- PSEN2 | c.269_270insCA p.M90Ifs*11 | Frame Shift Ins (INS) | VAF 59/210 reads (28%) | catalogued as COSV100423053; called by mutect2, pindel, varscan2
- PTMA | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV58187399; called by muse, mutect2, varscan2
- QDPR | c.209A>T p.E70V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV55550728; called by muse, mutect2, varscan2
- RASGRF2 | c.1489T>A p.L497I | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV54131898; called by muse, mutect2, varscan2
- RILP | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as rs760643404, COSV99557028; called by muse, mutect2, varscan2
- ROCK2 | c.128T>A p.V43E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV55080222; called by muse, mutect2, varscan2
- RPA4 | c.494A>T p.H165L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100232676; called by muse, mutect2, varscan2
- RYR1 | c.14817C>A p.D4939E | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs193922895, CM043571, COSV62100628; ClinVar: not provided; called by muse, mutect2, varscan2
- SALL4 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53853283, COSV53857001; called by muse, mutect2, varscan2
- SALL4 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); catalogued as rs765869556, COSV53853293; called by muse, mutect2, varscan2
- SDK2 | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV66188421; called by muse, mutect2
- SECISBP2 | c.575-2A>T p.X192_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as COSV60529044; called by muse, mutect2, varscan2
- SEMA3G | c.1928G>T p.R643L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as rs758884166, COSV51596224; called by muse, mutect2, varscan2
- SEMA4F | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60283754; called by muse, mutect2, varscan2
- SERPINB3 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.497); catalogued as rs377088096; called by muse, mutect2, varscan2
- SHANK2 | c.5231C>T p.P1744L | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99573844; called by muse, mutect2
- SLC23A3 | c.1320C>G p.F440L (on ENST00000409878 / NM_001144889.2; = p.F323L on NM_144712.5) | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as COSV55408001; called by muse, mutect2, varscan2
- SLC30A2 | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV65332863; called by muse, mutect2, varscan2
- SLC4A2 | c.3639G>A p.M1213I | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52540454; called by muse, mutect2, varscan2
- SLC6A9 | c.1819G>C p.G607R (on ENST00000360584 / NM_201649.4; = p.G553R on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.544); catalogued as COSV62211036; called by muse, mutect2, varscan2
- SLC9A2 | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs754828200, COSV52133185, COSV99296998; called by muse, mutect2, varscan2
- SNTG2 | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57988850; called by muse, mutect2, varscan2
- SNX20 | c.724C>A p.R242S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as rs1007232450, COSV56057321; called by muse, mutect2
- SOBP | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58000551; called by muse, mutect2, varscan2
- SPATA16 | c.1232A>G p.H411R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.165); catalogued as COSV63530247; called by muse, mutect2, varscan2
- SPTA1 | c.6727G>T p.D2243Y | Missense Mutation (SNP) | VAF 102/306 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63754966; called by muse, mutect2, varscan2
- SSX3 | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.106); catalogued as COSV53643139, COSV53644473; called by muse, mutect2
- ST3GAL2 | c.327G>C p.Q109H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | PolyPhen possibly damaging (0.526); catalogued as COSV61597062; called by muse, mutect2
- STK11 | c.527A>C p.D176A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064794805, COSV58825006, COSV58828366; ClinVar: uncertain significance; called by muse, mutect2
- TAGLN2 | c.180G>T p.T60= | Splice Region (SNP) | VAF 10/100 reads (10%) | catalogued as COSV100231132; called by muse, mutect2
- TET2 | c.1601G>C p.R534T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV54416240; called by muse, mutect2, varscan2
- THSD1 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.27); catalogued as COSV51629319; called by muse, mutect2, varscan2
- TMED10 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV57847931; called by muse, mutect2, varscan2
- TNRC18 | c.5242G>A p.A1748T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs376889645; called by muse, mutect2
- TRAK1 | c.2530G>T p.V844L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.204); catalogued as COSV59643858, COSV59644012; called by muse, mutect2, varscan2
- TRMT10C | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV59306098; called by muse, mutect2
- UNC79 | c.6508T>A p.W2170R (on ENST00000393151 / NM_001346218.2; = p.W1993R on NM_020818.5) | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56393120; called by muse, mutect2, varscan2
- UPRT | c.42C>A p.H14Q | Missense Mutation (SNP) | VAF 113/146 reads (77%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.021); catalogued as COSV64912420; called by muse, mutect2, varscan2
- VWA3B | c.2332A>G p.R778G | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV68243804; called by muse, mutect2, varscan2
- WDR72 | c.3072G>A p.M1024I | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV64748689; called by muse, mutect2, varscan2
- YES1 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 34/119 reads (29%) | catalogued as COSV58850769; called by muse, mutect2, varscan2
- YTHDF2 | c.280A>T p.N94Y | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV65723607; called by muse, mutect2, varscan2
- ZBBX | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56792161; called by muse, mutect2, varscan2
- ZBED9 | c.2254G>T p.G752C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV71729134, COSV71729495; called by muse, mutect2, varscan2
- ZDHHC4 | c.760C>G p.P254A | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60106684; called by muse, mutect2, varscan2
- ZFR | c.2812A>T p.T938S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV54054372; called by muse, mutect2, varscan2
- ZNF263 | c.1920C>G p.F640L | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV99526892; called by muse, mutect2, varscan2
- ZNF43 | c.2001A>T p.K667N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV61684372; called by muse, mutect2, varscan2
- AKR1C1 | c.814dup p.Y272Lfs*3 | Frame Shift Ins (INS) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
- ATAD3A | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- DDX31 | c.1364del p.P455Qfs*31 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.904C>A p.H302N | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OTOP2 | c.215_217del p.L72_A73delinsP | In Frame Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- TNS1 | c.4227del p.K1410Rfs*44 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | called by mutect2, pindel, varscan2
- ZNF98 | c.285del p.W95Cfs*13 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- ACSS3 | c.1299G>C p.L433= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV54093413, COSV99698371; called by muse, mutect2, varscan2
- ADAMTS15 | c.1191C>T p.I397= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs369731938; called by muse, mutect2, varscan2
- B4GALNT2 | c.1665C>T p.L555= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV55926727; called by muse, mutect2, varscan2
- CLASP1 | c.60A>T p.R20= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV55327468; called by muse, mutect2, varscan2
- CLDN18 | c.183C>A p.T61= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV59303124; called by mutect2, varscan2
- CSE1L | c.295T>C p.L99= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs898000207, COSV53702580; called by muse, mutect2
- CUX2 | c.3147G>A p.T1049= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs757600625, COSV55636299; called by muse, mutect2, varscan2
- DLX6 | c.531G>A p.L177= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV50294936; called by muse, mutect2, varscan2
- DNAH9 | c.9663C>T p.F3221= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV52355411; called by muse, mutect2, varscan2
- EFCAB1 | c.12G>A p.K4= | Silent (SNP) | VAF 23/180 reads (13%) | catalogued as COSV50618545; called by muse, mutect2, varscan2
- F5 | c.825C>A p.V275= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV63125164; called by muse, mutect2, varscan2
- GAB4 | c.261C>A p.S87= | Silent (SNP) | VAF 53/283 reads (19%) | catalogued as COSV68754145; called by muse, mutect2, varscan2
- GAS7 | c.564G>C p.P188= (on ENST00000432992 / NM_201433.2; = p.P48= on NM_003644.3) | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs777192634, COSV60431411, COSV60438018; called by muse, mutect2, varscan2
- GDA | c.51C>T p.F17= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs752892598, COSV52994202; called by muse, mutect2, varscan2
- GNPAT | c.1098C>T p.V366= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as COSV64153590; called by muse, mutect2, varscan2
- GP2 | c.729G>A p.L243= (on ENST00000381362 / NM_001007240.3; = p.L240= on NM_001502.4) | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV100221590, COSV56894648; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2817C>T p.S939= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV100441144; called by muse, mutect2, varscan2
- HSD17B14 | c.717G>T p.T239= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV54412534, COSV99622778; called by muse, mutect2
- ISCU | c.150G>T p.G50= (on ENST00000311893 / NM_213595.4; = p.G25= on NM_014301.4) | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV57208057; called by muse, mutect2, varscan2
- KIF24 | c.3747A>G p.E1249= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV52659536; called by muse, mutect2, varscan2
- LCOR | c.1386G>A p.R462= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs1328345675, COSV53716586; called by muse, mutect2, varscan2
- MYCBPAP | c.2037T>C p.S679= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as COSV60408822; called by muse, mutect2, varscan2
- MYH9 | c.495A>T p.R165= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV53387942; called by muse, mutect2, varscan2
- NAV2 | c.3543C>A p.L1181= (on ENST00000396087 / NM_001244963.2; = p.L1158= on NM_145117.5) | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV60660501; called by muse, mutect2, varscan2
- NDE1 | c.300C>T p.L100= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs189787660, COSV100706719, COSV61273237; ClinVar: likely benign; called by muse, mutect2, varscan2
- NINL | c.1536G>A p.S512= | Silent (SNP) | VAF 28/190 reads (15%) | catalogued as rs374076242; called by muse, mutect2, varscan2
- NKD1 | c.633A>C p.R211= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV51691842; called by muse, mutect2
- OR2T35 | c.258C>G p.L86= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, varscan2
- OR5H15 | c.429G>T p.R143= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV62948332; called by muse, mutect2, varscan2
- ORC2 | c.1359T>G p.P453= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV52239499; called by muse, mutect2
- PCDHAC1 | c.1002C>T p.N334= | Silent (SNP) | VAF 31/244 reads (13%) | catalogued as rs372774238, COSV53838314; called by muse, mutect2, varscan2
- PCDHGB4 | c.1263G>A p.T421= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as rs530113846, COSV53967547, COSV54034667; called by muse, mutect2, varscan2
- SHANK2 | c.5232A>T p.P1744= | Silent (SNP) | VAF 13/170 reads (8%) | catalogued as COSV99573835; called by muse, mutect2
- SLC24A2 | c.117C>A p.V39= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as rs1240698479, COSV53867171; called by muse, mutect2, varscan2
- SLC41A2 | c.1623C>T p.Y541= | Silent (SNP) | VAF 167/350 reads (48%) | catalogued as COSV51606534; called by muse, mutect2, varscan2
- SOBP | c.540G>C p.A180= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as COSV100433107, COSV58000453; called by muse, mutect2, varscan2
- SOGA1 | c.2925T>C p.N975= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs1476357685, COSV52921797; called by muse, mutect2, varscan2
- TGM4 | c.1066C>A p.R356= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs200982271, COSV56094500; called by muse, mutect2
- USF3 | c.111G>A p.G37= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV57074205; called by muse, mutect2, varscan2
- VCAM1 | c.474C>G p.L158= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV54120077; called by muse, mutect2, varscan2
- ZNF133 | c.1062C>T p.I354= (on ENST00000316358 / NM_001352454.2; = p.I353= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs747002893, COSV60367534; called by muse, mutect2, varscan2
- ZNF681 | c.879G>A p.Q293= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV101267462; called by muse, mutect2, varscan2
- ZNF804A | c.3069C>A p.I1023= | Silent (SNP) | VAF 42/183 reads (23%) | catalogued as COSV56453570; called by muse, mutect2, varscan2
- ZP4 | c.1029G>C p.R343= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV100850696, COSV100850718, COSV63912386; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148218 C>A | 5'Flank (SNP) | VAF 7/45 reads (16%) | called by mutect2, varscan2
- ALX1 | c.*1C>T | 3'UTR (SNP) | VAF 30/95 reads (32%) | catalogued as COSV100374399; called by muse, mutect2, varscan2
- LINC00303 | n.405C>A | RNA (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- POR | c.-4-10088C>T | Intron (SNP) | VAF 38/121 reads (31%) | catalogued as COSV100792802; called by muse, mutect2, varscan2
